Somatic mutation profile of tumor specimen TCGA-28-2502-01B (aliquot TCGA-28-2502-01B-01W-0837-08) from TCGA case TCGA-28-2502, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 65.2 years (23,807 days).
Specimen TCGA-28-2502-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 09db0a0a-1140-4f0a-9543-136a626e688c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-28-2502-10A (Blood Derived Normal), aliquot TCGA-28-2502-10A-01D-1494-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8e9c7c74-8713-4244-adfa-11f7f9054754

The open-access MAF lists 62 somatic variants for this specimen: 43 protein-altering or splice-affecting, 17 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 17, Frame Shift Del 3, Nonsense Mutation 3, In Frame Del 1, RNA 1, Frame Shift Ins 1, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CYP4F22 | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 61/280 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs776275777, COSV54107182, COSV54109072; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.212G>A p.C71Y | Missense Mutation (SNP) | VAF 15/41 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64295132, COSV64296674, COSV64298389; called by muse, mutect2, varscan2
- ABCA10 | c.541G>T p.G181* | Nonsense Mutation (SNP) | VAF 27/174 reads (16%) | catalogued as COSV52226483; called by muse, mutect2, varscan2
- ADAM30 | c.787C>T p.R263C | Missense Mutation (SNP) | VAF 49/143 reads (34%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.915); catalogued as rs200088734, COSV65561660; called by muse, mutect2, varscan2
- ADGRF5 | c.1183G>T p.G395C | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.106); catalogued as COSV51937387; called by muse, mutect2, varscan2
- ANKS6 | c.2034A>T p.L678F | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV62051199; called by muse, mutect2, varscan2
- ARHGAP17 | c.2440dup p.Q814Pfs*41 (on ENST00000289968 / NM_001006634.3; = p.Q736Pfs*41 on NM_018054.6) | Frame Shift Ins (INS) | VAF 10/78 reads (13%) | catalogued as rs773922861; called by mutect2, varscan2
- BPIFC | c.1149C>T p.F383= | Splice Region (SNP) | VAF 31/119 reads (26%) | catalogued as rs200868839, COSV55910552; called by muse, mutect2, varscan2
- C14orf39 | c.508C>T p.R170* | Nonsense Mutation (SNP) | VAF 4/28 reads (14%) | catalogued as rs754275662, COSV58783614; called by mutect2, varscan2
- C1QC | c.425C>T p.A142V | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.09); catalogued as rs769724909, COSV65889552; called by muse, mutect2, varscan2
- CDH18 | c.1288T>A p.F430I | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.63); PolyPhen benign (0.13); catalogued as COSV56942840, COSV56967332; called by muse, mutect2, varscan2
- CLCN7 | c.821A>G p.K274R | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.062); catalogued as rs775085622, COSV51970948; called by muse, mutect2, varscan2
- COL27A1 | c.3064G>A p.V1022M | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.143); catalogued as rs141446597; called by muse, mutect2, varscan2
- DNAI3 | c.1351C>G p.P451A | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.057); catalogued as COSV54004425; called by muse, mutect2
- EXD1 | c.447A>C p.E149D | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV59255419; called by muse, mutect2, varscan2
- FBLN2 | c.3325G>A p.A1109T | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.058); catalogued as rs1272556761, COSV55480844; called by muse, mutect2, varscan2
- FLG | c.10304G>A p.R3435H | Missense Mutation (SNP) | VAF 138/631 reads (22%) | SIFT tolerated (0.71); PolyPhen benign (0.02); catalogued as rs576274425, COSV64241308; called by muse, mutect2, varscan2
- GTF2H1 | c.875C>G p.S292C | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.619); catalogued as COSV56379321; called by muse, mutect2, varscan2
- H2BC1 | c.220C>T p.R74C | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.999); catalogued as rs766504742, COSV51237812; called by muse, mutect2, varscan2
- IFNGR2 | c.488T>C p.F163S | Missense Mutation (SNP) | VAF 106/917 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51640318; called by muse, mutect2, varscan2
- INTS12 | c.991G>A p.V331M | Missense Mutation (SNP) | VAF 66/426 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.048); catalogued as COSV60862962; called by muse, mutect2, varscan2
- MEI1 | c.3580G>C p.G1194R | Missense Mutation (SNP) | VAF 126/259 reads (49%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as COSV55905222; called by muse, mutect2, varscan2
- MEP1A | c.991G>A p.E331K | Missense Mutation (SNP) | VAF 35/142 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57921538; called by muse, mutect2, varscan2
- NF1 | c.499_502del p.C167Qfs*10 | Frame Shift Del (DEL) | VAF 10/36 reads (28%) | catalogued as rs786201874; called by pindel, varscan2
- OR2A42 | c.293C>T p.T98M | Missense Mutation (SNP) | VAF 63/172 reads (37%) | SIFT tolerated (0.75); PolyPhen benign (0.006); catalogued as rs764203936, COSV66955789; called by muse, mutect2, varscan2
- RYR3 | c.1006C>T p.R336* | Nonsense Mutation (SNP) | VAF 18/90 reads (20%) | catalogued as rs370675640; called by muse, mutect2, varscan2
- SCN10A | c.322C>T p.R108W | Missense Mutation (SNP) | VAF 169/818 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs1131691525, COSV71862254; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SEMA6D | c.989C>A p.A330E | Missense Mutation (SNP) | VAF 126/617 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100316950; called by muse, mutect2, varscan2
- SETD1A | c.1931C>G p.P644R | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV52690028, COSV52690414; called by muse, mutect2
- SPOCD1 | c.1346G>A p.R449K | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV57098061; called by muse, mutect2
- SYNE1 | c.22846C>T p.R7616W (on ENST00000367255 / NM_182961.4; = p.R7545W on NM_033071.3) | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200236760; called by mutect2, varscan2
- UGT2B28 | c.693G>T p.K231N | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.02); catalogued as COSV59433325; called by muse, mutect2, varscan2
- UNC93A | c.317C>T p.P106L | Missense Mutation (SNP) | VAF 18/234 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.344); catalogued as rs202053224, COSV57809723; called by muse, mutect2
- ZNF74 | c.1844C>T p.P615L | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); catalogued as COSV62622741; called by muse, mutect2
- ZNF831 | c.628G>A p.G210R | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.152); catalogued as rs1443345757, COSV64042957; called by muse, mutect2, varscan2
- ADAM29 | c.2070_2073delinsT p.L690_L691delinsF | In Frame Del (DEL) | VAF 5/26 reads (19%) | called by pindel, varscan2*
- CAT | c.1150G>A p.A384T | Missense Mutation (SNP) | VAF 20/157 reads (13%) | SIFT tolerated (0.71); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- FCRL3 | c.1936C>A p.L646M | Missense Mutation (SNP) | VAF 21/286 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); called by muse, mutect2
- H3-3B | c.252del p.R84Sfs*55 | Frame Shift Del (DEL) | VAF 40/72 reads (56%) | called by mutect2, pindel, varscan2
- PRUNE2 | c.5482G>A p.E1828K | Missense Mutation (SNP) | VAF 125/163 reads (77%) | SIFT deleterious (0.04); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- THBS3 | c.2762G>C p.C921S | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by mutect2, varscan2
- ZC3HC1 | c.755_756del p.S252Cfs*7 | Frame Shift Del (DEL) | VAF 30/152 reads (20%) | called by pindel, varscan2
- ZNF585A | c.650G>A p.S217N (on ENST00000292841 / NM_001288800.2; = p.S162N on NM_152655.3) | Missense Mutation (SNP) | VAF 14/302 reads (5%) | SIFT tolerated (0.75); PolyPhen benign (0.02); called by muse, mutect2
- ADGRG7 | c.1257T>C p.A419= | Silent (SNP) | VAF 12/101 reads (12%) | catalogued as COSV56299091; called by muse, mutect2, varscan2
- CASR | c.2100C>T p.I700= (on ENST00000490131; = p.I777= on NM_000388.4) | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as rs760608351, COSV56139438; ClinVar: likely benign; called by muse, mutect2, varscan2
- CCDC105 | c.1230G>A p.P410= | Silent (SNP) | VAF 21/310 reads (7%) | catalogued as rs773132972, COSV52964807; called by muse, mutect2
- CFAP157 | c.1218C>T p.V406= | Silent (SNP) | VAF 47/480 reads (10%) | called by muse, mutect2, varscan2
- CPN1 | c.300G>A p.S100= | Silent (SNP) | VAF 199/629 reads (32%) | catalogued as rs770069005, COSV64942566; called by muse, mutect2, varscan2
- DMPK | c.1269G>A p.L423= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as COSV52180288; called by muse, mutect2, varscan2
- FAM47B | c.1161G>A p.P387= | Silent (SNP) | VAF 23/42 reads (55%) | catalogued as rs758718114, COSV61455581; called by muse, mutect2, varscan2
- FFAR2 | c.370C>T p.L124= | Silent (SNP) | VAF 102/344 reads (30%) | catalogued as COSV55832863; called by muse, mutect2, varscan2
- GALNT8 | c.1011A>C p.A337= | Silent (SNP) | VAF 35/155 reads (23%) | catalogued as rs750840473; called by muse, mutect2, varscan2
- KDM5A | c.3666G>A p.R1222= | Silent (SNP) | VAF 28/91 reads (31%) | catalogued as COSV66994634; called by muse, mutect2, varscan2
- LPAR3 | c.330C>T p.D110= | Silent (SNP) | VAF 138/615 reads (22%) | catalogued as COSV65454359; called by muse, mutect2, varscan2
- MAP1B | c.1650A>G p.K550= | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as COSV57102968; called by muse, mutect2, varscan2
- MICB | c.543C>T p.R181= | Silent (SNP) | VAF 7/92 reads (8%) | catalogued as rs761060976, COSV52855261; called by muse, mutect2
- MUC17 | c.13197C>T p.V4399= | Silent (SNP) | VAF 42/272 reads (15%) | catalogued as rs762504748, COSV60296322; called by muse, mutect2, varscan2
- NOBOX | c.453C>T p.T151= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as rs780060226, COSV56196136; called by mutect2, varscan2
- PTPRM | c.2781C>T p.N927= | Silent (SNP) | VAF 48/227 reads (21%) | called by muse, mutect2, varscan2
- ZNF556 | c.858G>A p.P286= | Silent (SNP) | VAF 21/223 reads (9%) | catalogued as rs377206346; called by muse, mutect2, varscan2
- SNORD116-12 | n.22_24dup | RNA (INS) | VAF 26/127 reads (20%) | called by pindel, varscan2
- ZFHX3 | c.-533+99G>A | Intron (SNP) | VAF 14/72 reads (19%) | catalogued as rs375757471; called by muse, mutect2, varscan2
